CCDI case PBBPPV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/baacf0b5-85d7-40a2-ab0e-52113f5b5790

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.0 years (5,827 days).

Biospecimens (2 samples)
- Sample 0DEA0M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEA0R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
